Somatic mutation profile of tumor specimen TCGA-AP-A059-01A (aliquot TCGA-AP-A059-01A-21D-A122-09) from TCGA case TCGA-AP-A059, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 69.3 years (25,311 days).
Specimen TCGA-AP-A059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11f47e5b-a45c-44c9-8462-33d96079c391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A059-10A (Blood Derived Normal), aliquot TCGA-AP-A059-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fb7085b-ef63-4d3c-865f-7ddc88d9cd54

The open-access MAF lists 13,015 somatic variants for this specimen: 9,816 protein-altering or splice-affecting, 2,979 silent, 220 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8,706, Silent 2,979, Nonsense Mutation 689, Splice Site 259, Splice Region 99, Intron 83, RNA 64, 3'UTR 29, Frame Shift Del 29, Frame Shift Ins 23, 3'Flank 18, 5'UTR 16.

Variants (750 of 13,015; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs762114560, CM060001, COSV63720981; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACADVL | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 91/446 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs794727112, CM990100, COSV50039309; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, varscan2
- ACSF3 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 59/272 reads (22%) | catalogued as rs748382994, COSV58081378; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHDC1 | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as rs886041620, COSV55941432, COSV55942007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKT1 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1057519804, COSV62571663; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATF6 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761357250, CM156874, COSV63405743; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFAP43 | c.2802T>A p.C934* | Nonsense Mutation (SNP) | VAF 22/232 reads (9%) | catalogued as rs373911488, COSV99530224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs797044810, CM983859, COSV56582168; ClinVar: pathogenic; called by muse, mutect2
- CLN5 | c.*130G>A | 3'UTR (SNP) | VAF 52/204 reads (25%) | catalogued as rs28940280, CM980372, COSV100842302; ClinVar: pathogenic; called by muse, varscan2
- DMD | c.7657C>T p.R2553* | Nonsense Mutation (SNP) | VAF 107/548 reads (20%) | catalogued as rs398124050, CM040026, COSV58905803; ClinVar: pathogenic; called by muse, varscan2
- DOCK7 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | catalogued as rs1057520100, COSV52009369; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GCDH | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs121434372, CM960718, COSV99535611; ClinVar: pathogenic; called by muse, varscan2
- HSD17B3 | c.454-1G>A p.X152_splice | Splice Site (SNP) | VAF 29/163 reads (18%) | catalogued as rs1554694264, HS080011, COSV64558273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNC1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727502818, CM150707, COSV56398006; ClinVar: pathogenic; called by mutect2, varscan2
- KCNK3 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123040, CM136951, COSV57194402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIAA0753 | c.2656C>T p.R886* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as rs370840009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.3523C>T p.R1175* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs368078424; ClinVar: pathogenic; called by muse, mutect2
- KIF22 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs193922922, CM1110097, CM1110098, COSV50717277, COSV50717990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTM1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587783772, CM1513749, CM970999, COSV60337210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEB | c.19768C>T p.R6590* | Nonsense Mutation (SNP) | VAF 51/281 reads (18%) | catalogued as rs200731870, CM1413908; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 48/163 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1555611606, COSV62212655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR3C2 | c.2755C>T p.Q919* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as rs1553986377, COSV60998679; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5431C>T p.R1811* | Nonsense Mutation (SNP) | VAF 23/252 reads (9%) | catalogued as rs587784148, CD119747, CM031303, COSV61771006; ClinVar: pathogenic; called by muse, mutect2
- OCRL | c.2582-1G>T p.X861_splice | Splice Site (SNP) | VAF 32/181 reads (18%) | catalogued as rs398123289, CS113490, COSV63981789; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by pindel, varscan2
- PCNT | c.7819C>T p.R2607* | Nonsense Mutation (SNP) | VAF 57/192 reads (30%) | catalogued as rs749426946, COSV64032579; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX7 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs121909152, CM971145; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIGO | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as rs1199247059, COSV53055191, COSV99956971; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 147/318 reads (46%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.853); catalogued as rs141045127; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POU3F4 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs727505246, COSV100937296, COSV64541816; ClinVar: likely pathogenic; called by muse, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 25/57 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, varscan2
- PRF1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs28933973, CM992951, COSV64615781; ClinVar: pathogenic; called by muse, varscan2
- RAD50 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs772468452, COSV54749843, COSV99529486; ClinVar: pathogenic; called by muse, varscan2
- RHOBTB2 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1554504684, COSV52572914; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as rs794726778, CM083092, COSV57662848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC20A2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554561099, CM138546, COSV60603703; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC25A4 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs886041081, COSV55669674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.6856C>T p.R2286* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs312262785, CM091369, COSV55998184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPRED1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518150, COSV54438109, COSV54438678; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111426349, CM064321, CM139801, COSV66625981; ClinVar: pathogenic; called by mutect2, varscan2
- TNNC1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs730881058, COSV51767003; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 48/221 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.99169C>T p.R33057* (on ENST00000591111; = p.R25633* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as rs727504184, CM144268, COSV100587703; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.42769C>T p.R14257* (on ENST00000591111; = p.R6833* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 13/68 reads (19%) | catalogued as rs775186117, CM1514720, COSV59899605, COSV60000160; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBB4A | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as rs767399782, CM148654, COSV51158580; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- VPS33A | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767748011, COSV57358654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3962G>A p.C1321Y | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1470081414, COSV59391813; called by muse, mutect2, varscan2
- A2M | c.1586C>A p.P529H | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV59391828; called by muse, mutect2, varscan2
- A2ML1 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.546); catalogued as rs939451589, COSV100229480, COSV55297546; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV55297557; called by muse, mutect2, varscan2
- A4GNT | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 108/510 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52630001; called by muse, varscan2
- A4GNT | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52630013; called by muse, mutect2, varscan2
- AAAS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs756366173, COSV52932873, COSV52933392; called by muse, mutect2, varscan2
- AADACL2 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV100735625, COSV62929925; called by muse, mutect2
- AADAT | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV61788012; called by muse, mutect2, varscan2
- AAK1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68646389, COSV68646556; called by muse, mutect2
- AAMDC | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 52/181 reads (29%) | catalogued as COSV59020801; called by muse, mutect2, varscan2
- AARS1 | c.2321T>C p.L774P | Missense Mutation (SNP) | VAF 23/346 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV99933093; called by muse, mutect2
- AARS2 | c.2276C>A p.A759D | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.812); catalogued as COSV99771112; called by muse, mutect2
- AARS2 | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.163); catalogued as COSV99771115; called by muse, mutect2
- AASS | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV62791523; called by muse, varscan2
- AASS | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs370266183, COSV100741592, COSV62789109; called by mutect2, varscan2
- AASS | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as rs766257837, COSV62788740; called by muse, mutect2
- AATK | c.2801C>T p.A934V (on ENST00000326724 / NM_001080395.3; = p.A831V on NM_004920.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs773859753, COSV58372625; called by muse, mutect2, varscan2
- ABCA1 | c.3799C>T p.P1267S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV66069976; called by muse, mutect2, varscan2
- ABCA1 | c.1328G>T p.R443M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV66069988; called by muse, mutect2, varscan2
- ABCA10 | c.4016C>T p.T1339I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs769798989, COSV52228940; called by muse, mutect2, varscan2
- ABCA12 | c.7733G>A p.S2578N (on ENST00000272895 / NM_173076.3; = p.S2260N on NM_015657.3) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as COSV55973221; called by muse, mutect2, varscan2
- ABCA12 | c.6559G>A p.G2187S (on ENST00000272895 / NM_173076.3; = p.G1869S on NM_015657.3) | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.406); catalogued as COSV55973232; called by muse, mutect2, varscan2
- ABCA12 | c.3687G>T p.Q1229H (on ENST00000272895 / NM_173076.3; = p.Q911H on NM_015657.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55973245; called by mutect2, varscan2
- ABCA12 | c.1699G>T p.E567* (on ENST00000272895 / NM_173076.3; = p.E249* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 77/335 reads (23%) | catalogued as COSV55948386, COSV99792722; called by muse, mutect2, varscan2
- ABCA12 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV55973276, COSV99789901; called by muse, mutect2, varscan2
- ABCA13 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 105/494 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV70042306; called by muse, varscan2
- ABCA13 | c.1634A>C p.K545T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV70042357; called by muse, mutect2, varscan2
- ABCA13 | c.3468A>C p.E1156D | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV101329872; called by muse, mutect2, varscan2
- ABCA13 | c.3738A>T p.K1246N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.72); catalogued as COSV70027237, COSV70042392; called by muse, mutect2, varscan2
- ABCA13 | c.11180C>T p.T3727I | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753238434, COSV71293451; called by muse, mutect2, varscan2
- ABCA2 | c.4615G>A p.A1539T (on ENST00000614293; = p.A1509T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV55806051; called by muse, mutect2, varscan2
- ABCA2 | c.3109G>A p.A1037T (on ENST00000614293; = p.A1007T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748941494, COSV55806062; called by muse, varscan2
- ABCA5 | c.3996G>T p.L1332F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs751273723, COSV67018835; called by muse, mutect2, varscan2
- ABCA7 | c.5869G>T p.D1957Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54036526; called by muse, mutect2, varscan2
- ABCA8 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV52210476; called by muse, mutect2, varscan2
- ABCA8 | c.3593C>A p.S1198Y | Missense Mutation (SNP) | VAF 103/395 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV52197160; called by muse, mutect2, varscan2
- ABCA8 | c.2362C>T p.L788F | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs747896533, COSV52210507; called by muse, mutect2, varscan2
- ABCA8 | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 58/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290202195, COSV52210525; called by muse, varscan2
- ABCA9 | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs772870876, COSV100383418, COSV60630364; called by muse, mutect2, varscan2
- ABCA9 | c.2622C>A p.S874R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.163); catalogued as COSV60630373; called by muse, varscan2
- ABCA9 | c.1202C>A p.A401D | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV60630382; called by muse, varscan2
- ABCB1 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 33/153 reads (22%) | catalogued as COSV55961810; called by muse, varscan2
- ABCB1 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55961833; called by muse, mutect2, varscan2
- ABCB10 | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs141170788; called by mutect2, varscan2
- ABCB11 | c.391T>C p.L131= | Splice Region (SNP) | VAF 13/47 reads (28%) | catalogued as COSV55599676; called by muse, mutect2, varscan2
- ABCB4 | c.2914G>T p.D972Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.853); catalogued as COSV55941015; called by muse, mutect2, varscan2
- ABCB4 | c.2469A>C p.Q823H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV55941027; called by muse, mutect2, varscan2
- ABCB4 | c.2124G>A p.W708* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV55941044; called by muse, mutect2, varscan2
- ABCB5 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV51719343; called by muse, mutect2, varscan2
- ABCB5 | c.1487G>T p.R496I (on ENST00000404938 / NM_001163941.2; = p.R51I on NM_178559.6) | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV104385342, COSV51719356; called by muse, mutect2, varscan2
- ABCB5 | c.1632G>T p.K544N (on ENST00000404938 / NM_001163941.2; = p.K99N on NM_178559.6) | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51719393; called by muse, mutect2, varscan2
- ABCB7 | c.1813C>T p.R605* (on ENST00000373394 / NM_001271696.3; = p.R606* on NM_004299.6) | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV53723115; called by muse, mutect2, varscan2
- ABCB7 | c.944+1G>A p.X315_splice (on ENST00000373394 / NM_001271696.3; = p.X316_splice on NM_004299.6) | Splice Site (SNP) | VAF 12/79 reads (15%) | catalogued as COSV53722589, COSV53723121; called by muse, mutect2, varscan2
- ABCB9 | c.1508G>A p.R503Q (on ENST00000280560 / NM_019625.4; = p.R460Q on NM_019624.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs773009223, COSV54890710; called by muse, mutect2, varscan2
- ABCC1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60693100; called by muse, mutect2, varscan2
- ABCC11 | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62325512; called by muse, mutect2, varscan2
- ABCC11 | c.1296C>A p.F432L | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV62325517; called by muse, mutect2, varscan2
- ABCC11 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200134154; called by muse, mutect2, varscan2
- ABCC12 | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251959; called by muse, varscan2
- ABCC12 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100251961; called by muse, varscan2
- ABCC2 | c.1666C>A p.L556M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV64988345; called by muse, mutect2, varscan2
- ABCC2 | c.2620+1G>A p.X874_splice | Splice Site (SNP) | VAF 14/84 reads (17%) | catalogued as COSV64988347; called by muse, mutect2, varscan2
- ABCC2 | c.2731C>T p.R911* | Nonsense Mutation (SNP) | VAF 35/165 reads (21%) | catalogued as rs756825916, COSV64985495; called by muse, mutect2, varscan2
- ABCC4 | c.3736-1G>T p.X1246_splice | Splice Site (SNP) | VAF 43/167 reads (26%) | catalogued as COSV65317691; called by muse, mutect2, varscan2
- ABCC5 | c.4225G>A p.D1409N | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV55595600; called by muse, varscan2
- ABCC5 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV55595618; called by muse, varscan2
- ABCC8 | c.3982C>A p.L1328I | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs774965446, COSV56846416, COSV56856660; called by muse, mutect2, varscan2
- ABCC8 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as CM073990, COSV56856674; called by muse, mutect2, varscan2
- ABCC9 | c.3089C>T p.A1030V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV53983895; called by muse, mutect2, varscan2
- ABCC9 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV53983907; called by muse, mutect2, varscan2
- ABCC9 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs865881159, COSV53983935; called by muse, mutect2, varscan2
- ABCD2 | c.2001T>C p.L667= | Splice Region (SNP) | VAF 29/129 reads (22%) | catalogued as COSV58054645; called by muse, mutect2, varscan2
- ABCD3 | c.1663C>A p.L555I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV64644270; called by muse, mutect2, varscan2
- ABCD4 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 24/327 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100083921, COSV100084237; called by muse, mutect2
- ABCE1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs901361759, COSV56848861; called by muse, mutect2, varscan2
- ABCG2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV52948905; called by muse, mutect2, varscan2
- ABCG8 | c.201G>T p.Q67H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55396205; called by muse, mutect2, varscan2
- ABHD12 | c.749+1G>A p.X250_splice | Splice Site (SNP) | VAF 18/84 reads (21%) | catalogued as rs201317014, COSV59284467; called by muse, mutect2, varscan2
- ABHD12B | c.631G>A p.V211M (on ENST00000337334 / NM_001206673.2; = p.V134M on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769164034, COSV61570623; called by muse, mutect2, varscan2
- ABHD13 | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV65535410; called by muse, mutect2, varscan2
- ABHD14A | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 50/263 reads (19%) | catalogued as COSV56473512; called by muse, mutect2, varscan2
- ABHD16A | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV65452473; called by muse, mutect2, varscan2
- ABHD18 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750671699, COSV66293804; called by muse, mutect2, varscan2
- ABHD8 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV99917069; called by muse, mutect2
- ABI3BP | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52549404; called by muse, varscan2
- ABI3BP | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs75841780; called by muse, mutect2, varscan2
- ABL1 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.948); catalogued as COSV100583231, COSV100583805; called by muse, mutect2
- ABL2 | c.2597C>A p.S866Y (on ENST00000502732 / NM_007314.4; = p.S851Y on NM_005158.5) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV61020008; called by muse, mutect2, varscan2
- ABLIM2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315520248, COSV56408122; called by mutect2, varscan2
- ABRAXAS1 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58948947; called by muse, mutect2, varscan2
- AC004593.2 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.875); catalogued as COSV56100355; called by muse, mutect2, varscan2
- AC004922.1 | c.406C>T p.H136Y | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV99500839; called by muse, mutect2, varscan2
- AC004922.1 | c.1165G>T p.G389C | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV53164720; called by muse, mutect2, varscan2
- AC004922.1 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV99402737; called by muse, varscan2
- AC006059.2 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV59609165; called by mutect2, varscan2
- AC008676.3 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs761248863, COSV56637953; called by muse, mutect2, varscan2
- AC011455.2 | c.1691C>T p.T564I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs138608193, COSV55501435; called by muse, mutect2, varscan2
- AC011462.1 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54199480; called by muse, mutect2, varscan2
- AC011462.1 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781724398, COSV54199494; called by muse, varscan2
- AC013489.1 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV51553298; called by muse, mutect2, varscan2
- AC018630.4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV57392608; called by muse, varscan2
- AC092143.1 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV59247493, COSV59247824; called by muse, mutect2, varscan2
- AC092718.8 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.684); catalogued as COSV59602155; called by muse, varscan2
- AC092718.8 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 31/748 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59601430; called by muse, mutect2
- AC097637.1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as rs761464663, COSV59727445; called by mutect2, varscan2
- ACACA | c.6559C>T p.R2187* | Nonsense Mutation (SNP) | VAF 36/159 reads (23%) | catalogued as rs201499562; called by muse, mutect2, varscan2
- ACACB | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs200954726, COSV58144676; called by muse, mutect2, varscan2
- ACACB | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs773666938, COSV58131696; called by muse, varscan2
- ACACB | c.4456G>A p.D1486N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV58139820, COSV58141344; called by muse, mutect2, varscan2
- ACAD10 | c.1605C>A p.Y535* | Nonsense Mutation (SNP) | VAF 40/168 reads (24%) | catalogued as rs773702363, COSV58162528; called by muse, varscan2
- ACAD10 | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs1251428097, COSV58158694; called by muse, mutect2, varscan2
- ACAD10 | c.2039C>A p.P680H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58162550; called by muse, mutect2, varscan2
- ACAD9 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs779258809, COSV58309693; called by muse, mutect2, varscan2
- ACAD9 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs762081272, COSV58308494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACADL | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52055109; called by muse, mutect2, varscan2
- ACADM | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV57714585; called by muse, varscan2
- ACADS | c.755G>T p.S252I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV54370111; called by muse, mutect2, varscan2
- ACADSB | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV62551406; called by muse, mutect2, varscan2
- ACADVL | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as CS1312579, COSV50039307; called by muse, mutect2, varscan2
- ACAP2 | c.2064G>A p.G688= | Splice Region (SNP) | VAF 35/162 reads (22%) | catalogued as rs888367247, COSV58755185; called by muse, mutect2, varscan2
- ACAP2 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58755199; called by muse, mutect2, varscan2
- ACAP2 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV58755209; called by muse, mutect2, varscan2
- ACBD3 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64731122; called by muse, mutect2, varscan2
- ACBD5 | c.1348G>A p.A450T (on ENST00000375888 / NM_001352568.1; = p.A441T on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs749212781, COSV101022429, COSV65521536; called by muse, mutect2, varscan2
- ACBD6 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1360827828, COSV62575937; called by muse, mutect2, varscan2
- ACCSL | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs371000393, COSV66580564; called by mutect2, varscan2
- ACCSL | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.051); catalogued as COSV66582632; called by muse, mutect2, varscan2
- ACD | c.571G>A p.V191I (on ENST00000620338; = p.V102I on NM_022914.3) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV54670090; called by muse, mutect2, varscan2
- ACE | c.2090C>A p.T697N | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as rs765315607, COSV52012406; called by muse, varscan2
- ACE | c.2128A>G p.N710D | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV52012526; called by muse, varscan2
- ACE2 | c.697-1G>T p.X233_splice | Splice Site (SNP) | VAF 11/87 reads (13%) | catalogued as COSV53025416, COSV53026658; called by muse, mutect2, varscan2
- ACE2 | c.611G>T p.R204I | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53027328; called by muse, varscan2
- ACKR3 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV56023387; called by muse, mutect2, varscan2
- ACKR4 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs530056247, COSV51443423; called by muse, mutect2, varscan2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACO2 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53445030; called by muse, mutect2, varscan2
- ACO2 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs371183037; called by mutect2, varscan2
- ACOT1 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV58576929; called by muse, mutect2, varscan2
- ACOT12 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs371159125; called by muse, mutect2, varscan2
- ACOT12 | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56897662; called by muse, mutect2, varscan2
- ACOT2 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV53151453; called by muse, mutect2, varscan2
- ACOT7 | c.533C>A p.P178H (on ENST00000377855 / NM_181864.3; = p.P168H on NM_007274.4) | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV64115267; called by muse, mutect2, varscan2
- ACOX1 | c.1596C>A p.H532Q | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as COSV53136258; called by muse, mutect2, varscan2
- ACOX1 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV53136281; called by muse, mutect2, varscan2
- ACOX2 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1469348525, COSV57150577; called by muse, varscan2
- ACP3 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 87/357 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as rs769775568, COSV100668429, COSV63641046; called by muse, mutect2, varscan2
- ACP4 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV54518578; called by muse, mutect2, varscan2
- ACRBP | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 131/573 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV57525201; called by muse, mutect2, varscan2
- ACRV1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV59755339; called by muse, mutect2, varscan2
- ACSBG1 | c.2090G>A p.G697D | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99356872; called by muse, mutect2, varscan2
- ACSBG1 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs763637644, COSV51910108; called by muse, mutect2, varscan2
- ACSL1 | c.741C>A p.S247R | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as COSV55666173, COSV55666765; called by muse, varscan2
- ACSL1 | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs374585657, COSV55666047; called by muse, varscan2
- ACSL3 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as COSV62484577; called by muse, mutect2, varscan2
- ACSL3 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs1225801240, COSV62484587; called by muse, mutect2, varscan2
- ACSL4 | c.2117G>A p.R706Q (on ENST00000340800 / NM_022977.2; = p.R665Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/597 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as COSV61615679; called by muse, mutect2, varscan2
- ACSL4 | c.828G>A p.M276I (on ENST00000340800 / NM_022977.2; = p.M235I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178253903, COSV61615685; called by muse, mutect2, varscan2
- ACSL6 | c.2017A>T p.T673S (on ENST00000379240; = p.T698S on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/304 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57304426; called by muse, mutect2, varscan2
- ACSL6 | c.290G>A p.R97H (on ENST00000379240; = p.R122H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs199702305, COSV57304456; called by muse, mutect2, varscan2
- ACSM1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1000591628, COSV54639534; called by muse, mutect2, varscan2
- ACSM2B | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV61659752; called by muse, mutect2, varscan2
- ACSS1 | c.1830G>T p.Q610H | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV60224357; called by muse, mutect2, varscan2
- ACSS2 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53628011; called by muse, mutect2
- ACSS2 | c.1694C>A p.T565N | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53628023; called by muse, mutect2, varscan2
- ACSS3 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54085511; called by muse, mutect2, varscan2
- ACTB | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV59320079; called by muse, mutect2
- ACTC1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1437269590, COSV51757644, COSV99291859; called by muse, mutect2, varscan2
- ACTC1 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.428); catalogued as COSV51761187; called by muse, mutect2, varscan2
- ACTL6B | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.265); catalogued as COSV50517843; called by muse, mutect2, varscan2
- ACTL7A | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61777217; called by muse, mutect2, varscan2
- ACTL7B | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.766); catalogued as COSV65928089; called by muse, mutect2, varscan2
- ACTL9 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100185027, COSV61006502; called by muse, mutect2, varscan2
- ACTN1 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 38/205 reads (19%) | catalogued as COSV51996747; called by muse, varscan2
- ACTN1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752533755, COSV51995348; called by muse, mutect2, varscan2
- ACTN2 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63977868; called by muse, mutect2, varscan2
- ACTN4 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53144593; called by muse, mutect2, varscan2
- ACTN4 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs767795519, COSV53149909; called by muse, mutect2, varscan2
- ACTN4 | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.336); catalogued as COSV53149922; called by muse, mutect2, varscan2
- ACTR10 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.724); catalogued as COSV54299877; called by muse, mutect2, varscan2
- ACTR10 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs774617244, COSV54299888; called by muse, mutect2, varscan2
- ACTR2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV53203034; called by muse, mutect2, varscan2
- ACTR2 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV53203043; called by muse, mutect2, varscan2
- ACTRT2 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs556246890, COSV65760383, COSV65760418; called by muse, mutect2
- ACVR2A | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296122552, COSV54021353; called by muse, mutect2
- ACYP1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53135807; called by muse, mutect2, varscan2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, mutect2, varscan2
- ADAD2 | c.552G>T p.E184D (on ENST00000315906 / NM_001145400.2; = p.E256D on NM_139174.4) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV51894994; called by muse, varscan2
- ADAL | c.276A>C p.K92N | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV67501333; called by muse, mutect2, varscan2
- ADAM10 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53054425; called by muse, mutect2, varscan2
- ADAM12 | c.700C>A p.L234M | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV64113858; called by muse, mutect2, varscan2
- ADAM15 | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55127265, COSV55129509; called by muse, mutect2, varscan2
- ADAM15 | c.2143T>C p.Y715H | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99664552; called by muse, mutect2
- ADAM15 | c.2512C>A p.P838T (on ENST00000356955 / NM_207197.3; = p.P789T on NM_003815.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV55129527; called by muse, varscan2
- ADAM2 | c.189-1G>T p.X63_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | catalogued as COSV55867537; called by muse, mutect2, varscan2
- ADAM20 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV56456406; called by muse, mutect2, varscan2
- ADAM20 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99833299; called by muse, mutect2
- ADAM23 | c.1726G>T p.D576Y | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52228193; called by muse, mutect2, varscan2
- ADAM28 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1349281865, COSV56099265; called by muse, varscan2
- ADAM28 | c.1155G>T p.K385N | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99737256; called by muse, mutect2, varscan2
- ADAM28 | c.1830G>T p.K610N | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV56104787; called by muse, varscan2
- ADAM29 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.051); catalogued as COSV63667576; called by muse, mutect2, varscan2
- ADAM29 | c.2409G>T p.Q803H | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV63663923; called by muse, mutect2, varscan2
- ADAM33 | c.178-1G>A p.X60_splice | Splice Site (SNP) | VAF 19/111 reads (17%) | catalogued as COSV62936669; called by muse, mutect2, varscan2
- ADAM9 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65962053; called by muse, mutect2, varscan2
- ADAMTS1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568811671, COSV53173056; called by muse, mutect2, varscan2
- ADAMTS10 | c.2404-2A>G p.X802_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV54359012; called by muse, mutect2, varscan2
- ADAMTS12 | c.3565G>A p.V1189M | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100710019; called by muse, mutect2
- ADAMTS12 | c.2220C>A p.F740L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV61276788; called by muse, mutect2, varscan2
- ADAMTS16 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57005205; called by muse, mutect2, varscan2
- ADAMTS17 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs369507903, COSV51492127; called by muse, mutect2, varscan2
- ADAMTS18 | c.3344G>A p.C1115Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99270723; called by muse, varscan2
- ADAMTS18 | c.3284G>T p.R1095I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51412278, COSV51422246; called by muse, varscan2
- ADAMTS19 | c.2426-1G>A p.X809_splice | Splice Site (SNP) | VAF 35/131 reads (27%) | catalogued as COSV50791078; called by muse, mutect2, varscan2
- ADAMTS19 | c.2923C>T p.R975* | Nonsense Mutation (SNP) | VAF 34/162 reads (21%) | catalogued as rs780852099, COSV50733755; called by muse, mutect2, varscan2
- ADAMTS2 | c.3140G>A p.R1047H | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV52373048; called by muse, mutect2, varscan2
- ADAMTS20 | c.4230T>G p.C1410W | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67138119; called by muse, mutect2, varscan2
- ADAMTS20 | c.2709C>A p.D903E | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.175); catalogued as COSV67138127; called by muse, mutect2, varscan2
- ADAMTS3 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV54401033; called by muse, mutect2, varscan2
- ADAMTS3 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 70/325 reads (22%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as COSV54401042; called by muse, varscan2
- ADAMTS4 | c.2351A>G p.Q784R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV63491081; called by muse, mutect2, varscan2
- ADAMTS7 | c.2081G>A p.G694D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV101182980; called by muse, mutect2, varscan2
- ADAMTS9 | c.3581G>A p.C1194Y | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55789324; called by muse, mutect2, varscan2
- ADAMTSL1 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52824233; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4842C>A p.S1614R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as rs1247784468, COSV101000396; called by muse, mutect2
- ADAMTSL4 | c.1918G>T p.G640C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55006613; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs746430948, COSV54999417; called by mutect2, varscan2
- ADAP2 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV58297416; called by muse, mutect2, varscan2
- ADAP2 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV58297428; called by muse, mutect2, varscan2
- ADAR | c.3661T>A p.F1221I | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52720218; called by muse, mutect2, varscan2
- ADAR | c.2738T>C p.I913T | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264595536, CM070003; called by muse, mutect2
- ADAR | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.757); catalogued as COSV52720238; called by muse, mutect2, varscan2
- ADCK1 | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV53085266; called by muse, mutect2, varscan2
- ADCK2 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV50783313; called by muse, mutect2, varscan2
- ADCK5 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1554860530, COSV58235416; called by muse, mutect2, varscan2
- ADCK5 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58235423; called by muse, mutect2, varscan2
- ADCY10 | c.2784C>A p.F928L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63244356; called by muse, mutect2, varscan2
- ADCY10 | c.2171+1G>A p.X724_splice | Splice Site (SNP) | VAF 24/107 reads (22%) | catalogued as rs756985055, COSV63239101; called by muse, mutect2, varscan2
- ADCY10 | c.1916T>A p.I639N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV63244368; called by muse, mutect2, varscan2
- ADCY10 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.956); catalogued as COSV63242099, COSV63245739; called by muse, mutect2, varscan2
- ADCY4 | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs1383513234, COSV60257265; called by muse, mutect2, varscan2
- ADCY4 | c.771C>A p.S257R | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53477264; called by muse, mutect2, varscan2
- ADCY6 | c.2780A>C p.K927T | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV57170176; called by muse, mutect2, varscan2
- ADCY6 | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57167658; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV100416046; called by muse, mutect2
- ADD1 | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53273672; called by muse, mutect2, varscan2
- ADD2 | c.1698G>T p.E566D | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.134); catalogued as COSV100034296; called by muse, mutect2
- ADD3 | c.486+1G>T p.X162_splice | Splice Site (SNP) | VAF 29/147 reads (20%) | catalogued as COSV53325443; called by muse, varscan2
- ADGRA2 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 64/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100177963, COSV59446806; called by muse, mutect2, varscan2
- ADGRA3 | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV51567633; called by muse, mutect2, varscan2
- ADGRB3 | c.3640G>T p.G1214* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV53258259; called by muse, mutect2, varscan2
- ADGRD1 | c.955A>C p.N319H | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV55455785; called by muse, mutect2, varscan2
- ADGRE1 | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV51680277; called by muse, mutect2, varscan2
- ADGRE1 | c.2390C>T p.T797I | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51680301; called by muse, mutect2, varscan2
- ADGRE2 | c.2231C>T p.T744M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs759637864, COSV59694857; called by muse, varscan2
- ADGRF1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs141336103; called by mutect2, varscan2
- ADGRF1 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51947393; called by muse, mutect2, varscan2
- ADGRF3 | c.2725G>T p.G909W (on ENST00000311519 / NM_001145168.1; = p.G710W on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61052571, COSV61052847; called by muse, mutect2, varscan2
- ADGRF4 | c.1488G>T p.L496F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51956898; called by muse, mutect2, varscan2
- ADGRG1 | c.1843C>A p.L615I | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65636499; called by muse, mutect2, varscan2
- ADGRG4 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV54965380; called by muse, mutect2, varscan2
- ADGRG4 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV54961871, COSV54964537; called by muse, mutect2, varscan2
- ADGRG4 | c.3249C>A p.D1083E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV54965398; called by muse, mutect2, varscan2
- ADGRG4 | c.9224C>T p.P3075L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV54965413; called by muse, mutect2, varscan2
- ADGRG5 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs1218272069, COSV61084382; called by muse, mutect2, varscan2
- ADGRG7 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs376592781; called by muse, mutect2, varscan2
- ADGRL1 | c.2492C>T p.T831I (on ENST00000340736 / NM_001008701.3; = p.T826I on NM_014921.5) | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61566443; called by muse, mutect2, varscan2
- ADGRL1 | c.2360T>C p.F787S (on ENST00000340736 / NM_001008701.3; = p.F782S on NM_014921.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61566448; called by muse, mutect2, varscan2
- ADGRL1 | c.1327C>T p.P443S (on ENST00000340736 / NM_001008701.3; = p.P438S on NM_014921.5) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV61566453; called by muse, mutect2, varscan2
- ADGRL2 | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV54685881; called by muse, mutect2, varscan2
- ADGRL2 | c.3896A>G p.D1299G (on ENST00000370717 / NM_001366005.1; = p.D1243G on NM_012302.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs757054945, COSV54685896; called by muse, mutect2, varscan2
- ADGRL3 | c.3952C>A p.L1318M (on ENST00000506720 / NM_001322402.2; = p.L1207M on NM_015236.6) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV72230106; called by muse, mutect2, varscan2
- ADGRL4 | c.1598T>G p.F533C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66062180, COSV66065230; called by muse, mutect2, varscan2
- ADGRL4 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs1357607643, COSV100875476; called by muse, mutect2
- ADGRV1 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.133); catalogued as rs570271767, COSV101315252; called by muse, mutect2
- ADGRV1 | c.330A>C p.E110D | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67994054; called by muse, mutect2, varscan2
- ADGRV1 | c.1168T>C p.Y390H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs867362242, COSV67994060; called by muse, mutect2, varscan2
- ADGRV1 | c.7573T>C p.S2525P | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV67994067; called by muse, mutect2, varscan2
- ADGRV1 | c.14377A>T p.T4793S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV67994071; called by muse, varscan2
- ADGRV1 | c.17964G>A p.M5988I | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV67994078; called by muse, mutect2, varscan2
- ADH1C | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as COSV72463637; called by muse, mutect2, varscan2
- ADH6 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.904); catalogued as COSV52957616; called by muse, varscan2
- ADIPOQ | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.394); catalogued as rs771922005, COSV57859979; called by muse, mutect2, varscan2
- ADIPOR1 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579340; called by muse, mutect2, varscan2
- ADK | c.734C>T p.A245V (on ENST00000286621; = p.A228V on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54217735; called by muse, varscan2
- ADNP | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1470083745, COSV62425083; called by muse, mutect2, varscan2
- ADNP | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 26/128 reads (20%) | catalogued as COSV62424720; called by muse, mutect2, varscan2
- ADNP | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV62424517; called by muse, mutect2, varscan2
- ADNP2 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV51542027; called by muse, mutect2, varscan2
- ADNP2 | c.2753G>A p.C918Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51542041; called by muse, mutect2, varscan2
- ADORA2A | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV58380392; called by muse, mutect2, varscan2
- ADORA3 | c.89A>C p.N30T | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99598556; called by muse, mutect2
- ADRA1A | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767695098, COSV52356985; called by muse, mutect2, varscan2
- ADRA1B | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60703770; called by muse, mutect2, varscan2
- ADRB3 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV61462581; called by muse, mutect2, varscan2
- ADSL | c.356C>A p.T119N | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53410173; called by muse, mutect2, varscan2
- AEBP1 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV56260884; called by muse, mutect2, varscan2
- AEBP1 | c.1900C>A p.L634M | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as COSV56260895; called by muse, mutect2, varscan2
- AEBP1 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 102/446 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV56260906; called by muse, mutect2, varscan2
- AFAP1 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as COSV61798319; called by muse, mutect2, varscan2
- AFF2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 63/349 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.68); catalogued as COSV60679489; called by muse, mutect2, varscan2
- AFF2 | c.2813G>T p.G938V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.227); catalogued as COSV54005245; called by muse, mutect2
- AFG3L2 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52317051; called by muse, mutect2, varscan2
- AFM | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as COSV99888310, COSV99889172; called by muse, mutect2
- AFTPH | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as COSV53216188; called by muse, mutect2, varscan2
- AFTPH | c.2147A>G p.Y716C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53221497; called by muse, mutect2, varscan2
- AGA | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 87/431 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764539498, COSV52807062; called by muse, varscan2
- AGAP3 | c.823G>A p.V275M (on ENST00000622464; = p.V311M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.912); catalogued as rs768590477, COSV58994177, COSV99070584; called by muse, mutect2, varscan2
- AGBL5 | c.306T>G p.Y102* | Nonsense Mutation (SNP) | VAF 27/123 reads (22%) | catalogued as COSV59938094; called by muse, varscan2
- AGBL5 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1437800309, COSV59938107; called by muse, varscan2
- AGBL5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747191439, COSV59935370; called by muse, mutect2, varscan2
- AGK | c.975+1G>A p.X325_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | catalogued as rs868431923, COSV62595802; called by muse, mutect2, varscan2
- AGK | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV62595220, COSV62595807; called by muse, mutect2, varscan2
- AGL | c.3826G>T p.A1276S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.889); catalogued as COSV54057771; called by muse, mutect2, varscan2
- AGO2 | c.1029C>A p.V343= | Splice Region (SNP) | VAF 13/78 reads (17%) | catalogued as COSV55052160; called by muse, mutect2, varscan2
- AGPAT2 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58248655; called by muse, mutect2, varscan2
- AGPAT5 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373590213, COSV53449106; called by muse, mutect2, varscan2
- AGRN | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); catalogued as rs573358968, COSV65072075; called by muse, varscan2
- AGRN | c.4390C>T p.R1464C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs767005691, COSV65072080; called by mutect2, varscan2
- AGTPBP1 | c.3112C>T p.H1038Y (on ENST00000357081 / NM_001330701.2; = p.H998Y on NM_015239.2) | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV61276649; called by muse, mutect2, varscan2
- AHCTF1 | c.5938C>T p.P1980S (on ENST00000366508; = p.P1954S on NM_015446.5) | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58254443; called by muse, mutect2, varscan2
- AHCTF1 | c.4313C>T p.P1438L (on ENST00000366508; = p.P1412L on NM_015446.5) | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs773454962, COSV58254350, COSV58254453; called by muse, varscan2
- AHCTF1 | c.1832C>A p.S611Y (on ENST00000366508; = p.S585Y on NM_015446.5) | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58254464; called by muse, mutect2, varscan2
- AHCY | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV54154352; called by muse, mutect2, varscan2
- AHCYL2 | c.1601T>G p.F534C | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61488983; called by muse, mutect2, varscan2
- AHI1 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199922772, COSV55635046; called by muse, mutect2, varscan2
- AHI1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 134/533 reads (25%) | catalogued as COSV55635063; called by muse, mutect2, varscan2
- AHNAK | c.17029G>A p.E5677K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57227843, COSV99947929; called by muse, mutect2, varscan2
- AHNAK | c.11897C>T p.P3966L | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57227859; called by muse, mutect2, varscan2
- AHNAK | c.10980G>T p.K3660N | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57206237; called by muse, mutect2, varscan2
- AHNAK | c.8800G>A p.G2934S | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99945010; called by muse, mutect2
- AHNAK | c.6903G>T p.K2301N | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57227911; called by muse, mutect2, varscan2
- AHNAK | c.1828G>T p.V610L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV57227930; called by muse, mutect2, varscan2
- AHNAK | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV57227949; called by muse, varscan2
- AHNAK2 | c.10898C>T p.A3633V | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as COSV60928575; called by muse, mutect2, varscan2
- AHNAK2 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 186/920 reads (20%) | catalogued as COSV60928587; called by muse, mutect2, varscan2
- AHNAK2 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV60914645; called by muse, varscan2
- AHRR | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs760494595, COSV57092653; called by mutect2, varscan2
- AHRR | c.1394G>T p.S465I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV57092665, COSV57096148; called by muse, mutect2, varscan2
- AIFM2 | c.656A>C p.E219A | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV57160493; called by muse, mutect2, varscan2
- AIFM2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV57160517; called by muse, mutect2, varscan2
- AIG1 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1291953144, COSV51630806, COSV51634981; called by muse, mutect2, varscan2
- AIMP1 | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV63639478; called by muse, varscan2
- AIMP2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1393448099, COSV56151856; called by muse, mutect2, varscan2
- AIP | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54161751; called by muse, mutect2, varscan2
- AIRE | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52396740; called by muse, mutect2, varscan2
- AK9 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.97); catalogued as rs141208748; called by muse, varscan2
- AKAP1 | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV100027648; called by muse, mutect2, varscan2
- AKAP11 | c.155C>A p.A52D | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99213353; called by muse, mutect2
- AKAP11 | c.4224A>C p.E1408D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV50301445; called by muse, varscan2
- AKAP12 | c.3655G>T p.E1219* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV53581280; called by muse, mutect2, varscan2
- AKAP13 | c.6686G>A p.R2229Q (on ENST00000394518 / NM_007200.5; = p.R2233Q on NM_006738.6) | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs767950472, COSV63447693, COSV63469792; called by muse, mutect2, varscan2
- AKAP13 | c.7571G>T p.S2524I (on ENST00000394518 / NM_007200.5; = p.S2528I on NM_006738.6) | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63468037; called by muse, mutect2, varscan2
- AKAP17A | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1298110241, COSV58311745; called by muse, mutect2, varscan2
- AKAP3 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV57420043; called by muse, mutect2, varscan2
- AKAP3 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs146374513; called by mutect2, varscan2
- AKAP3 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57420073; called by muse, mutect2, varscan2
- AKAP3 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV99961637; called by muse, mutect2
- AKAP4 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1557203942, COSV100654098; called by muse, mutect2
- AKAP5 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57742938; called by muse, mutect2, varscan2
- AKAP6 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55230346; called by muse, mutect2, varscan2
- AKAP7 | c.602G>T p.R201M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV53836978; called by muse, mutect2, varscan2
- AKAP7 | c.946C>A p.L316M (on ENST00000431975 / NM_016377.4; = p.L49M on NM_004842.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV53836982; called by mutect2, varscan2
- AKAP8L | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs767032741, COSV68474469; called by mutect2, varscan2
- AKAP9 | c.4922C>T p.S1641F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs1306133822, COSV62356495; called by muse, mutect2, varscan2
- AKNA | c.4295G>T p.S1432I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV56339747; called by muse, varscan2
- AKR1B10 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV62056500; called by muse, mutect2, varscan2
- AKR1C3 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101002980; called by muse, mutect2
- AKR1C3 | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV65911072; called by muse, mutect2, varscan2
- AKR1D1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs368152787, COSV54338420; ClinVar: uncertain significance; called by muse, varscan2
- AKR1D1 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 24/130 reads (18%) | catalogued as COSV54340529, COSV54340543; called by muse, varscan2
- AKR7A2 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.642); catalogued as COSV99351877; called by muse, mutect2
- AKT3 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 35/186 reads (19%) | catalogued as COSV55606314; called by muse, mutect2, varscan2
- AKTIP | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV50886497; called by muse, mutect2, varscan2
- AL136295.1 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55781727; called by muse, mutect2, varscan2
- AL162417.1 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100923095; called by muse, mutect2
- AL441992.2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs778926559, COSV56916365; called by muse, mutect2, varscan2
- AL592490.1 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69427642; called by muse, mutect2, varscan2
- ALAS2 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58193011; called by muse, mutect2, varscan2
- ALAS2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.053); catalogued as rs780294973, COSV58193023; called by mutect2, varscan2
- ALB | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs267600248, COSV55736977, COSV55739910; called by muse, mutect2, varscan2
- ALDH16A1 | c.1438-2_1438-1insT p.X480_splice | Splice Site (INS) | VAF 15/98 reads (15%) | catalogued as COSV99512490; called by mutect2, pindel, varscan2
- ALDH1L1 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV56413535; called by muse, mutect2, varscan2
- ALDH3A1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56736699; called by muse, mutect2, varscan2
- ALDH3B2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62429251; called by muse, mutect2, varscan2
- ALDH4A1 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV51895682; called by muse, mutect2, varscan2
- ALDH5A1 | c.870+1G>A p.X290_splice | Splice Site (SNP) | VAF 21/121 reads (17%) | catalogued as CS033485, CS982403, COSV62374445; called by muse, mutect2, varscan2
- ALDH8A1 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774809603, COSV55640438; called by muse, varscan2
- ALDOC | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs758865156, COSV52026280; called by mutect2, varscan2
- ALG12 | c.1239-1G>T p.X413_splice | Splice Site (SNP) | VAF 21/95 reads (22%) | catalogued as COSV58208297; called by muse, mutect2, varscan2
- ALG12 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | PolyPhen possibly damaging (0.738); catalogued as rs908622724, COSV58208302; called by muse, varscan2
- ALG13 | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 85/333 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV52644316; called by muse, mutect2, varscan2
- ALG13 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV52644350; called by muse, mutect2, varscan2
- ALG9 | c.1388C>A p.P463H (on ENST00000614444 / NM_001352418.1; = p.P470H on NM_024740.2) | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as COSV101211827; called by muse, mutect2
- ALK | c.4346C>A p.S1449Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV66587154; called by muse, mutect2, varscan2
- ALKBH5 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV67687321; called by mutect2, varscan2
- ALLC | c.733A>C p.I245L | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV52997783; called by muse, mutect2, varscan2
- ALMS1 | c.3413C>T p.T1138I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.328); catalogued as COSV52520425; called by muse, varscan2
- ALMS1 | c.4323G>T p.Q1441H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV52520436; called by muse, mutect2, varscan2
- ALMS1 | c.10767G>T p.E3589D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV52520456; called by muse, varscan2
- ALOX12 | c.1684C>T p.R562W | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs768496365, COSV52348362; called by muse, mutect2, varscan2
- ALOXE3 | c.482G>T p.S161I | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV59077655; called by muse, mutect2, varscan2
- ALPG | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV54967929; called by muse, mutect2, varscan2
- ALPK1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99452680; called by muse, mutect2
- ALPK1 | c.3084G>T p.Q1028H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51590943; called by muse, varscan2
- ALPK2 | c.3840G>T p.K1280N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100863866; called by muse, mutect2
- ALPK2 | c.1918C>A p.L640I | Missense Mutation (SNP) | VAF 105/391 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV64494943, COSV64496563; called by muse, mutect2, varscan2
- ALPK2 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 81/284 reads (29%) | catalogued as rs755484511, COSV64496570, COSV64497004; called by muse, mutect2, varscan2
- ALPK3 | c.2417A>G p.H806R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV51940446, COSV99359923; called by muse, mutect2
- ALPK3 | c.2633G>A p.S878N | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV51938411; called by muse, mutect2, varscan2
- ALPK3 | c.4931C>T p.S1644F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV51939109; called by muse, mutect2, varscan2
- ALPL | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV66380730; called by muse, mutect2, varscan2
- ALS2CL | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV59673387; called by muse, mutect2, varscan2
- ALX3 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs1348561420, COSV63929081; called by muse, mutect2, varscan2
- ALYREF | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs781729860, COSV58668468; called by muse, mutect2, varscan2
- AMBN | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV59827908; called by muse, mutect2, varscan2
- AMBP | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs1313320293, COSV54325376; called by muse, mutect2, varscan2
- AMBRA1 | c.3782C>T p.P1261L (on ENST00000458649 / NM_001367468.1; = p.P1171L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54061620; called by muse, mutect2, varscan2
- AMD1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV64388184; called by muse, mutect2, varscan2
- AMELX | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV61634821; called by muse, mutect2, varscan2
- AMER1 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.341); catalogued as COSV57655563, COSV57666772; called by muse, mutect2, varscan2
- AMER1 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs746320756, COSV57666792; called by muse, mutect2, varscan2
- AMER2 | c.1591G>T p.G531C | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63440037; called by muse, mutect2, varscan2
- AMER3 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as rs190739558; called by muse, mutect2, varscan2
- AMIGO2 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56974571; called by muse, mutect2, varscan2
- AMOT | c.2755G>A p.A919T (on ENST00000371959 / NM_001113490.1; = p.A510T on NM_133265.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.88); PolyPhen possibly damaging (0.483); catalogued as COSV59067568; called by muse, varscan2
- AMOTL1 | c.1539T>G p.D513E | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV58570177; called by muse, varscan2
- AMPD1 | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62418511; called by muse, mutect2, varscan2
- AMPD1 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815206, COSV62417288; called by muse, mutect2, varscan2
- AMPD2 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs1473278743, COSV56650339; called by muse, mutect2, varscan2
- AMY2B | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as rs377067814, COSV63714132; called by muse, mutect2, varscan2
- AMZ1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs922352369, COSV56687848; called by muse, mutect2, varscan2
- ANAPC1 | c.4958C>T p.A1653V | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV61979060; called by muse, mutect2, varscan2
- ANAPC2 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.525); catalogued as COSV60572111; called by muse, mutect2, varscan2
- ANAPC2 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs764001056, COSV59244550; called by muse, mutect2, varscan2
- ANAPC2 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as COSV58808897; called by muse, mutect2, varscan2
- ANAPC7 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101482827; called by muse, mutect2
- ANGEL1 | c.1811T>C p.I604T | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51875310; called by muse, mutect2, varscan2
- ANGEL1 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV51875319; called by muse, mutect2, varscan2
- ANGEL1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs368520839; called by muse, mutect2, varscan2
- ANGPT1 | c.1011C>A p.F337L | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52454943; called by muse, mutect2, varscan2
- ANGPT2 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.121); catalogued as COSV57339939; called by muse, mutect2, varscan2
- ANGPTL2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs770228069, COSV52218903; called by muse, mutect2, varscan2
- ANGPTL3 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV52019501; called by muse, mutect2, varscan2
- ANGPTL3 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV52019512; called by muse, mutect2, varscan2
- ANGPTL5 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 102/493 reads (21%) | catalogued as rs1336895541, COSV57534435; called by muse, mutect2, varscan2
- ANGPTL6 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1366372112, COSV53463716; called by muse, mutect2, varscan2
- ANK1 | c.2921G>T p.R974M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99223366; called by muse, mutect2
- ANK1 | c.2426C>T p.T809I | Missense Mutation (SNP) | VAF 64/291 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1047932071, COSV55893666; called by muse, mutect2, varscan2
- ANK1 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 25/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99223374; called by muse, mutect2
- ANK1 | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99698311; called by muse, mutect2
- ANK2 | c.9889T>G p.F3297V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99998648; called by muse, mutect2
- ANK3 | c.12409T>G p.L4137V (on ENST00000280772 / NM_001320874.2; = p.L658V on NM_001149.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55062952, COSV55078541; called by muse, mutect2, varscan2
- ANKFY1 | c.2050C>T p.P684S (on ENST00000341657 / NM_001330063.2; = p.P685S on NM_016376.5) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.038); catalogued as COSV58921792; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4413G>T p.Q1471H | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV99781638; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.4476G>T p.E1492D | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.074); catalogued as COSV99781643; called by muse, varscan2
- ANKK1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV58274034; called by muse, mutect2, varscan2
- ANKLE1 | c.1061G>T p.R354M (on ENST00000394458; = p.R300M on NM_152363.6) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.402); catalogued as COSV63921546; called by muse, mutect2, varscan2
- ANKMY1 | c.1810C>A p.L604M | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99800877; called by muse, mutect2
- ANKMY2 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1193175953, COSV61012607; called by muse, mutect2, varscan2
- ANKRD1 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65467931, COSV65468319; called by muse, mutect2
- ANKRD1 | c.415T>G p.F139V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV63311181; called by muse, mutect2, varscan2
- ANKRD11 | c.603C>A p.G201= | Splice Region (SNP) | VAF 31/113 reads (27%) | catalogued as COSV56370356; called by muse, mutect2, varscan2
- ANKRD12 | c.4190C>T p.T1397I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV50844060; called by muse, mutect2, varscan2
- ANKRD12 | c.6151G>A p.V2051I | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV50844110; called by muse, mutect2, varscan2
- ANKRD13C | c.1451A>C p.E484A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV52034549; called by muse, mutect2, varscan2
- ANKRD17 | c.4114C>A p.L1372M | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58226824; called by muse, mutect2, varscan2
- ANKRD17 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58226836; called by muse, mutect2, varscan2
- ANKRD26 | c.1272T>C p.S424= | Splice Region (SNP) | VAF 30/207 reads (14%) | catalogued as COSV101065940; called by muse, mutect2, varscan2
- ANKRD28 | c.2363C>A p.A788D | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs370066621; called by muse, varscan2
- ANKRD30A | c.1252G>A p.A418T (on ENST00000611781; = p.A362T on NM_052997.2) | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs372362957; called by muse, mutect2, varscan2
- ANKRD35 | c.1946G>A p.S649N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1553739116, COSV62910832; called by muse, mutect2, varscan2
- ANKRD36B | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 32/181 reads (18%) | catalogued as COSV51536556; called by muse, varscan2
- ANKRD40 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 82/311 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.056); catalogued as COSV53328074; called by muse, mutect2, varscan2
- ANKRD42 | c.935G>T p.R312M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52617964; called by muse, mutect2, varscan2
- ANKRD50 | c.3235C>T p.R1079C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72386224; called by muse, mutect2, varscan2
- ANKRD52 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.275); catalogued as COSV57287162; called by muse, mutect2, varscan2
- ANKRD55 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61950126; called by muse, varscan2
- ANKRD6 | c.1720C>A p.L574I (on ENST00000339746 / NM_001242809.2; = p.L569I on NM_014942.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV60236373; called by muse, mutect2, varscan2
- ANKS1B | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV61352778; called by muse, mutect2, varscan2
- ANO1 | c.2408T>C p.F803S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755612025, COSV62449399; called by muse, mutect2, varscan2
- ANO10 | c.1712G>A p.C571Y | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780698368, COSV52735570; called by muse, varscan2
- ANO2 | c.1741G>T p.A581S (on ENST00000356134 / NM_001278597.3; = p.A585S on NM_001278596.3) | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59040667; called by muse, mutect2, varscan2
- ANO2 | c.1437G>T p.Q479H (on ENST00000356134 / NM_001278597.3; = p.Q483H on NM_001278596.3) | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV59040695; called by muse, varscan2
- ANO3 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1161758979, COSV56785162; called by muse, mutect2, varscan2
- ANO3 | c.2669A>G p.Y890C | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56806469; called by muse, mutect2, varscan2
- ANO4 | c.377G>T p.R126I (on ENST00000392977 / NM_001286615.2; = p.R91I on NM_178826.4) | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV54611081; called by muse, varscan2
- ANO4 | c.1020-1G>A p.X340_splice (on ENST00000392977 / NM_001286615.2; = p.X305_splice on NM_178826.4) | Splice Site (SNP) | VAF 29/125 reads (23%) | catalogued as COSV54611094; called by muse, mutect2, varscan2
- ANO4 | c.2356G>A p.A786T (on ENST00000392977 / NM_001286615.2; = p.A751T on NM_178826.4) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54594065; called by muse, mutect2, varscan2
- ANO5 | c.549T>A p.H183Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV61089705; called by muse, mutect2, varscan2
- ANO5 | c.1436C>A p.A479D | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV61089710; called by muse, varscan2
- ANO7 | c.1836-1G>T p.X612_splice (on ENST00000274979; = p.X558_splice on NM_001370694.2) | Splice Site (SNP) | VAF 18/386 reads (5%) | catalogued as COSV99236964; called by muse, mutect2
- ANO8 | c.2420A>G p.K807R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV50197384; called by muse, varscan2
- ANO9 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.481); catalogued as COSV100241128, COSV60451601; called by muse, mutect2, varscan2
- ANP32B | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as rs761031783, COSV59587727; called by muse, mutect2, varscan2
- ANPEP | c.1784G>A p.R595K | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs1384882302, COSV55594414; called by muse, varscan2
- ANPEP | c.1287G>A p.W429* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as rs749638276, COSV55594421; called by muse, mutect2, varscan2
- ANPEP | c.615-1G>T p.X205_splice | Splice Site (SNP) | VAF 14/113 reads (12%) | catalogued as COSV55594444; called by muse, mutect2, varscan2
- ANTXR2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV99786289; called by muse, varscan2
- ANXA10 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63740108, COSV63740195; called by muse, mutect2, varscan2
- ANXA10 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as COSV63738360; called by muse, mutect2, varscan2
- ANXA11 | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99626622; called by muse, mutect2
- ANXA13 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.217); catalogued as COSV51626298; called by muse, mutect2, varscan2
- ANXA2R | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV59215230; called by muse, mutect2, varscan2
- ANXA6 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758088547, COSV62909015; called by muse, mutect2
- ANXA6 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1033202779, COSV62908137; called by muse, mutect2, varscan2
- ANXA8 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1255805570; called by muse, varscan2
- ANXA9 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV64485500; called by muse, mutect2, varscan2
- AOC3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs766793528, COSV53828577; called by mutect2, varscan2
- AOX1 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65983711; called by muse, varscan2
- AP002748.5 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV59151444; called by muse, mutect2, varscan2
- AP1G1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55494574; called by muse, mutect2, varscan2
- AP1G1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55494605; called by muse, mutect2, varscan2
- AP1G2 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV55339074; called by muse, mutect2, varscan2
- AP1M1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV52228630; called by muse, mutect2, varscan2
- AP1M2 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as rs1387796687, COSV51569190; called by muse, mutect2, varscan2
- AP2B1 | c.1049A>C p.N350T | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as COSV52003012; called by muse, mutect2, varscan2
- AP2B1 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52003019; called by muse, mutect2, varscan2
- AP3B1 | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs1283996817; called by muse, mutect2, varscan2
- AP3B1 | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV54891689; called by muse, mutect2, varscan2
- AP3D1 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs764644332, COSV61432346; called by mutect2, varscan2
- AP3S1 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1215954730, COSV57476958; called by muse, mutect2, varscan2
- AP4B1 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV56726746; called by muse, mutect2, varscan2
- AP5B1 | c.2353C>A p.L785I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as COSV57504099; called by muse, varscan2
- AP5B1 | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1465455929, COSV57504121; called by muse, varscan2
- AP5Z1 | c.140G>T p.R47M | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62243547; called by muse, mutect2, varscan2
- AP5Z1 | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62243557; called by muse, mutect2, varscan2
- APBB1 | c.1608G>T p.K536N | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV54980107; called by muse, mutect2, varscan2
- APBB1 | c.1550C>A p.S517Y | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.809); catalogued as COSV54980118, COSV54980444; called by muse, varscan2
- APBB1 | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV54980136; called by muse, mutect2, varscan2
- APBB2 | c.2254C>T p.R752C (on ENST00000295974 / NM_001166050.2; = p.R753C on NM_004307.2) | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768084121, COSV55961072; called by muse, mutect2, varscan2
- APC | c.7536T>G p.S2512R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.129); catalogued as COSV57377169; called by muse, varscan2
- APEX2 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66624440; called by muse, mutect2, varscan2
- APLF | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs199832884, COSV58148267; called by mutect2, varscan2
- APLP1 | c.1484T>C p.L495S | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.518); catalogued as COSV55706600; called by muse, mutect2, varscan2
- APLP2 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as COSV53843919; called by muse, mutect2, varscan2
- APLP2 | c.1959+1G>A p.X653_splice | Splice Site (SNP) | VAF 46/247 reads (19%) | catalogued as rs1184491062, COSV53843923; called by muse, mutect2, varscan2
- APOB | c.12239T>A p.V4080D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV51950061; called by muse, varscan2
- APOBEC1 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 101/489 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV57549979; called by muse, mutect2, varscan2
- APOBEC3C | c.447C>A p.D149E | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV53328467; called by muse, mutect2, varscan2
- APOL4 | c.413G>T p.R138I (on ENST00000352371 / NM_145660.2; = p.R135I on NM_030643.4) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60655301; called by muse, mutect2, varscan2
- APOLD1 | c.516C>A p.F172L (on ENST00000326765 / NM_001130415.2; = p.F141L on NM_030817.3) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.098); catalogued as COSV100458364, COSV58733754; called by muse, mutect2
- APP | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61004096; called by muse, mutect2, varscan2
- APPBP2 | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | catalogued as COSV50029051; called by muse, mutect2, varscan2
- AQP9 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs752063676, COSV54970571; called by muse, mutect2, varscan2
- AQR | c.3131T>C p.L1044S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50049671; called by muse, mutect2, varscan2
- AQR | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs762010505, COSV50049796; called by muse, mutect2, varscan2
- ARAF | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 60/229 reads (26%) | catalogued as COSV51694996; called by muse, mutect2, varscan2
- ARAP2 | c.1858-1G>T p.X620_splice | Splice Site (SNP) | VAF 29/125 reads (23%) | catalogued as COSV58291428; called by muse, mutect2, varscan2
- ARAP2 | c.965-1G>A p.X322_splice | Splice Site (SNP) | VAF 15/73 reads (21%) | catalogued as COSV58282395, COSV58291435; called by muse, mutect2, varscan2
- ARAP2 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | catalogued as COSV58291440; called by muse, mutect2, varscan2
- ARAP3 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99499156; called by muse, mutect2
- AREL1 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as rs769282593, COSV62667903; called by muse, mutect2, varscan2
- ARF3 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs753931886, COSV56741779; called by muse, mutect2, varscan2
- ARF3 | c.235A>G p.R79G | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV56741785; called by muse, mutect2, varscan2
- ARF5 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as rs1286936912, COSV50001634; called by muse, mutect2, varscan2
- ARF6 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.41); catalogued as COSV53598169; called by muse, mutect2, varscan2
- ARFGAP1 | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV62263919; called by muse, varscan2
- ARFGAP2 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60302112; called by muse, mutect2, varscan2
- ARFGAP3 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs746663640, COSV54314191; called by muse, mutect2, varscan2
- ARFGEF3 | c.5163T>G p.H1721Q | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776976914, COSV52469258; called by muse, mutect2, varscan2
- ARFGEF3 | c.6520G>A p.D2174N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99291880; called by muse, mutect2
- ARHGAP20 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52818196; called by muse, mutect2, varscan2
- ARHGAP20 | c.630C>T p.Y210= | Splice Region (SNP) | VAF 39/186 reads (21%) | catalogued as rs771316747, COSV52818215; called by muse, mutect2, varscan2
- ARHGAP21 | c.5186C>T p.S1729L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs776145004, COSV57601850; called by muse, mutect2, varscan2
- ARHGAP21 | c.4781C>T p.T1594I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV57610436; called by muse, mutect2, varscan2
- ARHGAP21 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.279); catalogued as COSV57610445; called by muse, mutect2, varscan2
- ARHGAP22 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs923056868, COSV50978934; called by muse, mutect2, varscan2
- ARHGAP24 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs571519833, COSV67834201; called by muse, mutect2, varscan2
- ARHGAP24 | c.1266G>T p.K422N (on ENST00000395184 / NM_001025616.3; = p.K329N on NM_031305.3) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV51993069; called by muse, mutect2, varscan2
- ARHGAP26 | c.992A>T p.E331V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV50839583; called by muse, mutect2, varscan2
- ARHGAP30 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV63518949; called by muse, mutect2, varscan2
- ARHGAP31 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51798180; called by muse, mutect2, varscan2
- ARHGAP31 | c.2531G>T p.S844I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV51792170, COSV51798196; called by muse, varscan2
- ARHGAP31 | c.3842G>A p.C1281Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs775544822, COSV51798202; called by mutect2, varscan2
- ARHGAP32 | c.4273G>A p.A1425T (on ENST00000310343 / NM_001378025.1; = p.A1076T on NM_014715.4) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.019); catalogued as COSV59854847; called by muse, mutect2, varscan2
- ARHGAP33 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs763204420, COSV50155165; called by muse, mutect2, varscan2
- ARHGAP35 | c.3199C>T p.Q1067* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV68335269; called by muse, mutect2, varscan2
- ARHGAP39 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419399892, COSV99430036; called by muse, mutect2
- ARHGAP44 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99309791; called by muse, mutect2
- ARHGAP44 | c.1816G>T p.G606C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV52401410; called by muse, mutect2, varscan2
- ARHGAP5 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61538973; called by muse, mutect2, varscan2
- ARHGAP5 | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1275599319, COSV61538980; called by muse, mutect2, varscan2
- ARHGAP6 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV100273134, COSV57302366; called by muse, mutect2, varscan2
- ARHGAP6 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV61627080, COSV61628854, COSV61634824; called by muse, mutect2, varscan2
- ARHGAP9 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs772404087, COSV62724355; called by muse, mutect2, varscan2
- ARHGEF1 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1555848409, COSV61529446; called by muse, mutect2, varscan2
- ARHGEF1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV61527800; called by muse, mutect2, varscan2
- ARHGEF10L | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV63424560; called by muse, mutect2, varscan2
- ARHGEF10L | c.1382G>T p.R461M | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV51439634; called by muse, mutect2, varscan2
- ARHGEF10L | c.3262G>A p.V1088I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.397); catalogued as rs145857867; called by muse, mutect2, varscan2
- ARHGEF11 | c.2496C>A p.F832L | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.431); catalogued as COSV100169090, COSV59358187; called by mutect2, varscan2
- ARHGEF12 | c.1659G>T p.K553N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV63107041; called by muse, mutect2, varscan2
- ARHGEF12 | c.2557C>T p.R853* | Nonsense Mutation (SNP) | VAF 41/203 reads (20%) | catalogued as COSV63106137; called by muse, mutect2, varscan2
- ARHGEF15 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.384); catalogued as rs766415435, COSV62724296; called by muse, mutect2, varscan2
- ARHGEF17 | c.3838G>T p.D1280Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99734653; called by muse, mutect2
- ARHGEF17 | c.5312C>T p.A1771V | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs746780248, COSV55237256; called by muse, mutect2, varscan2
- ARHGEF18 | c.1369C>T p.R457C (on ENST00000359920 / NM_001130955.2; = p.R353C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776496814, COSV60473517; called by muse, varscan2
- ARHGEF19 | c.1463C>A p.P488H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV54618432; called by muse, mutect2, varscan2
- ARHGEF19 | c.1204T>G p.F402V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54618449; called by muse, mutect2, varscan2
- ARHGEF19 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as COSV54618458; called by muse, mutect2, varscan2
- ARHGEF25 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV54090077; called by muse, mutect2, varscan2
- ARHGEF28 | c.435G>T p.L145F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.841); catalogued as COSV55267861; called by muse, mutect2, varscan2
- ARHGEF28 | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV55267875; called by muse, mutect2, varscan2
- ARHGEF28 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV55267890; called by muse, mutect2, varscan2
- ARHGEF3 | c.1556G>A p.S519N | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV56331873; called by muse, mutect2, varscan2
- ARHGEF37 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV61370162; called by muse, mutect2, varscan2
- ARHGEF40 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 27/84 reads (32%) | catalogued as COSV53883861; called by muse, mutect2, varscan2
- ARHGEF40 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768330300, COSV53878795; called by muse, mutect2, varscan2
- ARHGEF5 | c.4774C>A p.L1592M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436036899, COSV50217935; called by muse, mutect2, varscan2
- ARHGEF6 | c.1354T>C p.F452L | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV51695448; called by muse, mutect2, varscan2
- ARHGEF6 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.438); catalogued as rs761900156, COSV51695490; called by muse, mutect2, varscan2
- ARHGEF7 | c.1735G>A p.V579I (on ENST00000375741 / NM_001113511.2; = p.V401I on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs1273332333, COSV54550455; called by muse, mutect2, varscan2
- ARHGEF7 | c.2467-1G>T p.X823_splice (on ENST00000646102 / NM_001354046.1; = p.X607_splice on NM_003899.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 35/155 reads (23%) | catalogued as COSV54550488; called by muse, mutect2, varscan2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- ARID1A | c.2252-1G>T p.X751_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as COSV61387681; called by muse, varscan2
- ARID1A | c.5093A>G p.D1698G | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100249874; called by muse, mutect2
- ARID1A | c.6341C>T p.P2114L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773818181, COSV61371709; called by muse, mutect2, varscan2
- ARID2 | c.3482C>T p.A1161V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV57613283; called by muse, mutect2, varscan2
- ARID2 | c.4993G>T p.G1665W | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57604735; called by muse, mutect2, varscan2
- ARID4B | c.2665C>A p.L889I | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.952); catalogued as rs755714856, COSV51610010; called by muse, mutect2, varscan2
- ARID5A | c.1269G>T p.K423N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.617); catalogued as rs775267535, COSV62591734; called by muse, mutect2, varscan2
- ARID5B | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV54428621; called by muse, mutect2, varscan2
- ARIH1 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV65912836; called by muse, mutect2, varscan2
- ARL1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1159806718, COSV55370968; called by muse, mutect2, varscan2
- ARL13A | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 86/401 reads (21%) | catalogued as rs374188162, COSV71448328; called by muse, mutect2, varscan2
- ARL14 | c.333A>C p.E111D | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.14); catalogued as COSV57900399; called by muse, varscan2
- ARL15 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72292464, COSV72292873; called by muse, mutect2, varscan2
- ARL16 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.38); catalogued as rs779031827, COSV61270072; called by muse, mutect2, varscan2
- ARL6IP1 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs748922543, COSV58614904; called by muse, mutect2, varscan2
- ARL6IP1 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58614908; called by muse, mutect2, varscan2
- ARL6IP4 | c.1027A>G p.T343A (on ENST00000315580 / NM_018694.3; = p.T324A on NM_016638.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54907640; called by muse, varscan2
- ARMC12 | c.274A>C p.S92R (on ENST00000373866 / NM_001286574.2; = p.S119R on NM_145028.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV55361473; called by muse, mutect2, varscan2
- ARMC2 | c.2188C>T p.H730Y | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs1420230001, COSV64553029; called by muse, mutect2, varscan2
- ARMC3 | c.1880G>A p.S627N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as COSV53066660; called by muse, mutect2, varscan2
- ARMC3 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 33/153 reads (22%) | catalogued as rs1183815996, COSV53058777; called by muse, mutect2, varscan2
- ARMC6 | c.557C>T p.T186I (on ENST00000392336; = p.T161I on NM_033415.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV54183898; called by muse, varscan2
- ARMC6 | c.608G>A p.R203H (on ENST00000392336; = p.R178H on NM_033415.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs373198003; called by muse, varscan2
- ARMCX1 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV65705480; called by muse, mutect2, varscan2
- ARMCX2 | c.1516C>T p.L506F | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV57531048; called by muse, mutect2
- ARMCX2 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as COSV57531059; called by muse, mutect2, varscan2
- ARMCX3 | c.77G>T p.R26I | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV57871523; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.885); catalogued as COSV63438925; called by muse, mutect2, varscan2
- ARMCX6 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782019037, COSV62680933; called by muse, mutect2, varscan2
- ARMH4 | c.1893G>T p.E631D | Missense Mutation (SNP) | VAF 60/734 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99957372; called by muse, mutect2
- ARMH4 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV50772149; called by muse, mutect2, varscan2
- ARNT | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 25/148 reads (17%) | catalogued as COSV62232098; called by muse, mutect2, varscan2
- ARNT2 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 62/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs141193900; called by muse, mutect2, varscan2
- ARNTL2 | c.1460G>A p.S487N | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as COSV53828557; called by muse, mutect2, varscan2
- ARPP21 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51806961; called by muse, mutect2, varscan2
- ARRB1 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV63574973, COSV63577327; called by muse, varscan2
- ARRB1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs951534835, COSV63577337; called by muse, mutect2, varscan2
- ARRB2 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.864); catalogued as rs777117300, COSV52618618; called by muse, mutect2, varscan2
- ARRDC4 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 72/440 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs367878363; called by muse, mutect2, varscan2
- ARSH | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as rs1279616557, COSV66963800; called by muse, varscan2
- ARSK | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1478829084, COSV66169781; called by muse, mutect2, varscan2
- ART4 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV57453144; called by muse, mutect2, varscan2
- ART5 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV51706832; called by mutect2, varscan2
- ARVCF | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54269762; called by muse, mutect2, varscan2
- ASAH1 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as COSV50504126; called by muse, mutect2, varscan2
- ASAP1 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV63053803; called by muse, mutect2, varscan2
- ASAP2 | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55637742; called by muse, varscan2
- ASAP2 | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99855522; called by muse, varscan2
- ASB1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs150540319; called by muse, varscan2
- ASB1 | c.728T>C p.V243A | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV52828146; called by muse, varscan2
- ASB10 | c.784T>C p.S262P (on ENST00000420175 / NM_001142459.2; = p.S247P on NM_080871.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs6948380, COSV99317961; called by muse, varscan2
- ASB10 | c.658C>T p.H220Y (on ENST00000420175 / NM_001142459.2; = p.H205Y on NM_080871.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99317964; called by muse, varscan2
- ASB14 | c.1350T>G p.C450W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55703187; called by muse, mutect2, varscan2
- ASB15 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1481373914, COSV51928706; called by muse, mutect2, varscan2
- ASB15 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51928718; called by muse, mutect2, varscan2
- ASB16 | c.234A>C p.Q78H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV53236248; called by muse, mutect2, varscan2
- ASB18 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.434); catalogued as COSV58235637; called by muse, varscan2
- ASB3 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55079577; called by muse, varscan2
- ASB4 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV57508874; called by muse, varscan2
- ASB5 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 61/214 reads (29%) | catalogued as COSV56673882; called by muse, mutect2, varscan2
- ASB5 | c.197-1G>T p.X66_splice | Splice Site (SNP) | VAF 31/109 reads (28%) | catalogued as COSV56673762, COSV56673891; called by muse, mutect2, varscan2
- ASF1A | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57648708; called by muse, mutect2, varscan2
- ASH1L | c.5599T>C p.F1867L | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100853023; called by muse, mutect2
- ASH1L | c.3962G>A p.R1321Q | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); catalogued as rs1358026443, COSV64205657; called by muse, mutect2, varscan2
- ASH2L | c.1702C>A p.L568M | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51701590; called by muse, mutect2, varscan2
- ASIC1 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 24/136 reads (18%) | catalogued as rs1362476233, COSV57319990; called by muse, mutect2, varscan2
- ASL | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59189327; called by muse, mutect2, varscan2
- ASMTL | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 60/246 reads (24%) | catalogued as COSV67245092; called by muse, mutect2, varscan2
- ASMTL | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs749599167, COSV67244646; called by muse, mutect2
- ASNS | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.129); catalogued as COSV51555730; called by muse, mutect2, varscan2
- ASNSD1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53624783; called by muse, mutect2, varscan2
- ASPHD2 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 70/285 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1192540003, COSV53219670; called by muse, mutect2, varscan2
- ASPM | c.9940G>A p.E3314K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV54137466; called by muse, mutect2, varscan2
- ASPM | c.6235G>T p.G2079C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV54137472; called by muse, mutect2, varscan2
- ASPM | c.3197T>G p.L1066* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV54137503; called by muse, mutect2, varscan2
- ASPM | c.2603C>A p.P868H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54137511; called by muse, mutect2, varscan2
- ASS1 | c.68G>T p.W23L | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100752432; called by muse, mutect2
- ASTE1 | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV53910280; called by muse, mutect2, varscan2
- ASTN1 | c.2041C>A p.L681I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV56082649; called by muse, mutect2, varscan2
- ASTN1 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 100/468 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs143274107, COSV56082666; called by muse, mutect2, varscan2
- ASTN2 | c.3725C>T p.S1242F (on ENST00000313400 / NM_001365069.1; = p.S1191F on NM_014010.5) | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV56013559; called by muse, mutect2, varscan2
- ASTN2 | c.1484C>A p.A495D (on ENST00000313400 / NM_001365069.1; = p.A444D on NM_014010.5) | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57813387; called by muse, mutect2, varscan2
- ASTN2 | c.1307C>T p.A436V (on ENST00000313400 / NM_001365069.1; = p.A385V on NM_014010.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100523432; called by muse, mutect2
- ASXL1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV60120675; called by muse, mutect2, varscan2
- ASXL2 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV99709853; called by muse, mutect2
- ASXL2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 51/232 reads (22%) | catalogued as COSV55453315, COSV55459595; called by muse, mutect2, varscan2
- ASXL3 | c.3566G>T p.S1189I | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52477811; called by muse, varscan2
12,265 further variants in this file (9,067 protein-altering or splice-affecting, 2,979 silent, 219 other) are not listed here.
